Somatic mutation profile of tumor specimen MMRF_1555_1_BM_CD138pos (aliquot MMRF_1555_1_BM_CD138pos_T1_KBS5U_L05378) from MMRF case MMRF_1555, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 83.2 years (30,380 days).
Specimen MMRF_1555_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 959573d7-2085-4bf4-851b-18e84e6961e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1555_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1555_1_PB_Whole_C2_KBS5U_L05390; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22e31214-6fff-4fe9-b250-8daac0ace5ea

The open-access MAF lists 226 somatic variants for this specimen: 88 protein-altering or splice-affecting, 27 silent, 111 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, 3'UTR 57, Intron 28, Silent 27, 3'Flank 12, 5'UTR 6, Nonsense Mutation 5, RNA 4, 5'Flank 4, Frame Shift Del 3, Splice Site 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2ML1 | c.2747C>T p.S916L | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.579); catalogued as COSV55291817; called by muse, mutect2, varscan2
- ADAMTS15 | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 85/171 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54509010; called by muse, mutect2, varscan2
- ARHGDIB | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480554458; called by muse, mutect2, varscan2
- C1orf131 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.154); catalogued as rs762365587; called by muse, mutect2, varscan2
- CFAP52 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as rs754402594; called by muse, mutect2, varscan2
- CSMD2 | c.8537G>A p.R2846H | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.513); catalogued as rs775463572, COSV53879418; called by muse, mutect2, varscan2
- DLGAP2 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as rs774180756, COSV70097614; called by muse, mutect2, varscan2
- EDA2R | c.517G>T p.G173* | Nonsense Mutation (SNP) | VAF 30/64 reads (47%) | catalogued as COSV53631303; called by muse, mutect2, varscan2
- EP300 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV54341868; called by muse, mutect2
- FAM110B | c.1099G>T p.V367F | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs376100419; called by muse, mutect2, varscan2
- FAT3 | c.12311G>A p.R4104Q | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs1310916962, COSV53093990; called by muse, mutect2, varscan2
- FOLH1 | c.1999C>T p.Q667* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | catalogued as COSV99923850; called by muse, mutect2, varscan2
- FRMPD2 | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV59718591, COSV59722838; called by muse, mutect2, varscan2
- GRB14 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 49/92 reads (53%) | SIFT tolerated (0.8); PolyPhen benign (0.019); catalogued as rs144801972; called by muse, mutect2, varscan2
- H2BC4 | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV58416213; called by muse, mutect2, varscan2
- HELB | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as COSV99922142; called by muse, mutect2, varscan2
- IGF2R | c.6061G>A p.G2021R | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as rs1378274585, COSV100807345; called by muse, mutect2
- IGHV2-70 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 62/72 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs371486752; called by muse, varscan2
- IGLV5-45 | c.198G>T p.Q66H | Missense Mutation (SNP) | VAF 69/124 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs187611736; called by muse, varscan2
- IGLV7-46 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1415265529; called by muse, mutect2
- IKBKB | c.511A>G p.K171E | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1217007648, COSV60595911, COSV60598768; called by muse, mutect2, varscan2
- IL1RL2 | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1193561518, COSV51818145; called by muse, mutect2, varscan2
- IPO9 | c.2692C>T p.R898C | Missense Mutation (SNP) | VAF 59/75 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144727362; called by muse, mutect2, varscan2
- KIF7 | c.3452G>A p.R1151H | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs900395454; called by muse, mutect2, varscan2
- LARS1 | c.994A>G p.R332G (on ENST00000394434 / NM_020117.11; = p.R305G on NM_016460.3) | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.294); catalogued as rs772937922; called by muse, mutect2, varscan2
- MAGI1 | c.2557C>T p.R853C (on ENST00000402939 / NM_001033057.2; = p.R881C on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371939525; called by muse, mutect2, varscan2
- MYO3A | c.2998C>T p.R1000W | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs1360882511, COSV56334269; called by muse, mutect2, varscan2
- OBI1 | c.72+1G>T p.X24_splice | Splice Site (SNP) | VAF 65/102 reads (64%) | catalogued as rs770203448; called by muse, mutect2, varscan2
- OR4K13 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs774402943; called by muse, mutect2, varscan2
- PLXNA3 | c.2043+7C>T | Splice Region (SNP) | VAF 5/56 reads (9%) | catalogued as rs375016053; called by muse, mutect2
- PPP1R16B | c.1055C>T p.S352L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as rs764537147; called by muse, mutect2, varscan2
- RABGAP1 | c.2397dup p.L800Tfs*11 | Frame Shift Ins (INS) | VAF 28/82 reads (34%) | catalogued as rs1472414271; called by mutect2, varscan2
- SLCO6A1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV65813139; called by muse, mutect2, varscan2
- SMARCB1 | c.953_955del p.K318del (on ENST00000263121; = p.K364del on NM_003073.5) | In Frame Del (DEL) | VAF 40/104 reads (38%) | catalogued as rs875989800; called by pindel, varscan2
- TDRD1 | c.3308G>A p.C1103Y | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.165); catalogued as rs1197160998; called by muse, mutect2, varscan2
- TMEM94 | c.1176dup p.T393Dfs*55 | Frame Shift Ins (INS) | VAF 51/116 reads (44%) | catalogued as rs746649748; called by mutect2, pindel, varscan2
- TRIP12 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV52266700; called by muse, mutect2, varscan2
- TRPM3 | c.2888G>A p.R963H (on ENST00000357533 / NM_001366142.2; = p.R806H on NM_020952.6) | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1447088660, COSV62595993; called by muse, mutect2, varscan2
- ZBTB45 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as rs781408189; called by muse, mutect2, varscan2
- ADGRL4 | c.965A>G p.Y322C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- AKNA | c.2362_2368del p.E788Rfs*51 | Frame Shift Del (DEL) | VAF 37/78 reads (47%) | called by mutect2, pindel, varscan2
- ANKRD27 | c.1525C>A p.Q509K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARID4B | c.865A>C p.K289Q | Missense Mutation (SNP) | VAF 18/299 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2
- ARIH1 | c.52A>C p.S18R | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 44/82 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- C12orf40 | c.1085T>A p.L362* | Nonsense Mutation (SNP) | VAF 28/51 reads (55%) | called by muse, mutect2, varscan2
- CACNG7 | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CLK1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- CNKSR2 | c.1130G>A p.G377E | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL20A1 | c.2539G>C p.V847L | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CSF2RA | c.117G>T p.R39S | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CSRNP3 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 71/143 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DMBT1 | c.7090A>T p.T2364S (on ENST00000338354 / NM_001377530.1; = p.T1607S on NM_004406.3) | Missense Mutation (SNP) | VAF 75/173 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- ELOA | c.881G>C p.R294T | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EP300 | c.1267A>T p.K423* | Nonsense Mutation (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- ESRP1 | c.1963G>A p.G655S | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- FAM170A | c.838C>G p.Q280E | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GON7 | c.116A>T p.Q39L | Missense Mutation (SNP) | VAF 49/87 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- HDAC7 | c.1852T>C p.C618R (on ENST00000427332; = p.C657R on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ILRUN | c.671A>T p.E224V (on ENST00000374023 / NM_024294.4; = p.E158V on NM_022758.6) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IPO9 | c.2356C>T p.L786F | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KDM5B | c.2674G>A p.D892N | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.062); called by muse, mutect2
- KMT2A | c.214G>C p.A72P | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT39 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LIMK1 | c.104G>C p.G35A | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MAP3K14 | c.2353C>G p.P785A | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- NTRK2 | c.1666G>A p.E556K (on ENST00000323115 / NM_001369534.1; = p.E572K on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2
- OLFM3 | c.994G>T p.G332C (on ENST00000338858 / NM_001288821.1; = p.G312C on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR12D1 | c.325_340del p.E109Pfs*2 | Frame Shift Del (DEL) | VAF 47/132 reads (36%) | called by mutect2, pindel, varscan2
- OTOG | c.7990G>A p.D2664N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- PHLPP1 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2
- PLXNA4 | c.1214G>T p.C405F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PPP2CB | c.868G>A p.D290N | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRG2 | c.586C>T p.H196Y | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); called by mutect2, varscan2
- PRR27 | n.122-1G>C | Splice Site (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- RC3H1 | c.352+1G>C p.X118_splice | Splice Site (SNP) | VAF 22/191 reads (12%) | called by muse, mutect2, varscan2
- RPL5 | c.175_176del p.D59Yfs*53 | Frame Shift Del (DEL) | VAF 36/150 reads (24%) | called by pindel, varscan2
- RPL5 | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- SEC24C | c.1626_1628dup p.S543dup | In Frame Ins (INS) | VAF 29/65 reads (45%) | called by mutect2, pindel, varscan2
- SLC39A14 | c.1219T>C p.C407R | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLC4A7 | c.1398G>T p.R466S | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPATA5L1 | c.1697T>G p.I566S | Missense Mutation (SNP) | VAF 96/191 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SPTA1 | c.4339G>A p.E1447K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.518); called by muse, mutect2
- SYNGAP1 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- TGIF1 | c.331A>C p.N111H (on ENST00000330513 / NM_001374396.1; = p.N131H on NM_003244.4) | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TXNDC9 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- USP24 | c.5520T>G p.I1840M | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- YTHDC1 | c.1030C>T p.Q344* (on ENST00000344157 / NM_001031732.4; = p.Q326* on NM_133370.4) | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- ADAMTSL5 | c.955C>T p.L319= | Silent (SNP) | VAF 14/66 reads (21%) | called by muse, mutect2, varscan2
- ATP8A2 | c.399C>T p.I133= | Silent (SNP) | VAF 28/39 reads (72%) | called by muse, mutect2, varscan2
- CA4 | c.30C>T p.L10= | Silent (SNP) | VAF 30/92 reads (33%) | called by muse, mutect2, varscan2
- CERCAM | c.1551A>G p.A517= | Silent (SNP) | VAF 42/102 reads (41%) | called by muse, mutect2, varscan2
- CGNL1 | c.942G>T p.L314= | Silent (SNP) | VAF 34/259 reads (13%) | catalogued as COSV99848916; called by muse, mutect2, varscan2
- CRACD | c.1131G>A p.A377= | Silent (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- EPPK1 | c.6645C>T p.R2215= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs74184133, COSV101599820, COSV73260919, COSV73261079; called by muse, mutect2, varscan2
- FAM50A | c.969C>T p.R323= | Silent (SNP) | VAF 48/290 reads (17%) | called by muse, mutect2, varscan2
- FBLN7 | c.267C>T p.D89= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as rs368980413, COSV100485427; called by muse, mutect2, varscan2
- GPR148 | c.711C>T p.N237= | Silent (SNP) | VAF 25/96 reads (26%) | called by muse, mutect2, varscan2
- JAK2 | c.1713T>C p.G571= | Silent (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- LINGO2 | c.1500G>A p.V500= | Silent (SNP) | VAF 60/164 reads (37%) | called by muse, mutect2, varscan2
- MESP2 | c.174C>T p.S58= | Silent (SNP) | VAF 19/33 reads (58%) | called by muse, mutect2, varscan2
- MEX3C | c.741C>T p.I247= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as rs1444303302; called by muse, mutect2
- MGAM2 | c.1977A>G p.R659= | Silent (SNP) | VAF 55/174 reads (32%) | called by muse, mutect2, varscan2
- MROH2A | c.3823C>T p.L1275= | Silent (SNP) | VAF 78/160 reads (49%) | called by muse, mutect2, varscan2
- MYLPF | c.309C>T p.A103= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs1199181516; called by muse, mutect2, varscan2
- NLGN4X | c.501C>T p.P167= | Silent (SNP) | VAF 36/70 reads (51%) | catalogued as rs780407397; called by muse, mutect2, varscan2
- PIGR | c.1332C>T p.N444= | Silent (SNP) | VAF 34/195 reads (17%) | catalogued as rs749036004; called by muse, mutect2, varscan2
- PRDM8 | c.873C>G p.G291= | Silent (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- RPL3L | c.12G>T p.R4= | Silent (SNP) | VAF 32/63 reads (51%) | catalogued as COSV51906737; called by muse, mutect2, varscan2
- RWDD2A | c.15G>A p.V5= | Silent (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- STK32C | c.396C>T p.R132= | Silent (SNP) | VAF 116/260 reads (45%) | catalogued as rs746412785, COSV53839949; called by muse, mutect2, varscan2
- TECTA | c.4260C>T p.I1420= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV50698583; called by muse, mutect2, varscan2
- TRDN | c.1728C>G p.P576= | Silent (SNP) | VAF 49/97 reads (51%) | catalogued as COSV62129759; called by muse, mutect2, varscan2
- XIAP | c.27T>A p.S9= | Silent (SNP) | VAF 84/204 reads (41%) | called by muse, mutect2, varscan2
- ZNF577 | c.531G>A p.Q177= | Silent (SNP) | VAF 56/117 reads (48%) | called by muse, mutect2, varscan2
- ABCB8 | chr7:151046446 G>T | 3'Flank (SNP) | VAF 53/111 reads (48%) | called by muse, mutect2, varscan2
- AC099489.1 | c.3865-41C>T | Intron (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- ADCY2 | c.*702C>T | 3'UTR (SNP) | VAF 41/83 reads (49%) | called by muse, mutect2, varscan2
- AFF2 | c.*3838C>A | 3'UTR (SNP) | VAF 25/77 reads (32%) | called by muse, mutect2, varscan2
- AGPAT3 | c.*2584C>G | 3'UTR (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
- AK9 | c.3633+13del | Intron (DEL) | VAF 8/52 reads (15%) | catalogued as rs577355457, COSV58140597, COSV58141900; called by pindel, varscan2
- AL353804.4 | chrX:73820660 C>T | 3'Flank (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- AL441992.2 | c.*5094G>A | 3'UTR (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- ALB | chr4:73404261 T>C | 5'Flank (SNP) | VAF 33/248 reads (13%) | called by muse, mutect2, varscan2
- ANO5 | c.*2073C>T | 3'UTR (SNP) | VAF 32/137 reads (23%) | called by muse, mutect2, varscan2
- ARPC4-TTLL3 | c.330+1914C>T | Intron (SNP) | VAF 42/87 reads (48%) | called by muse, mutect2, varscan2
- ARSJ | c.*1445C>T | 3'UTR (SNP) | VAF 5/66 reads (8%) | catalogued as rs1398065020; called by muse, mutect2
- ATL2 | c.*354T>G | 3'UTR (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- B4GALT5 | c.*111C>T | 3'UTR (SNP) | VAF 68/133 reads (51%) | called by muse, mutect2, varscan2
- BOC | c.2021-47G>A | Intron (SNP) | VAF 34/84 reads (40%) | called by muse, mutect2, varscan2
- C14orf132 | chr14:96089841 G>A | 3'Flank (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- C19orf12 | chr19:29700749 C>T | 3'Flank (SNP) | VAF 13/82 reads (16%) | called by muse, mutect2, varscan2
- C1D | c.139-44C>T | Intron (SNP) | VAF 21/48 reads (44%) | catalogued as rs1558580925; called by muse, mutect2, varscan2
- CCR10 | c.-11T>G | 5'UTR (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- CD200R1L | c.*99G>T | 3'UTR (SNP) | VAF 108/248 reads (44%) | called by muse, mutect2, varscan2
- CDC37 | c.488-34G>A | Intron (SNP) | VAF 32/330 reads (10%) | called by muse, mutect2
- CELSR3 | c.*107del | 3'UTR (DEL) | VAF 12/120 reads (10%) | called by mutect2, pindel, varscan2
- CLPTM1 | c.793+88C>G | Intron (SNP) | VAF 13/26 reads (50%) | catalogued as rs568694846; called by muse, mutect2, varscan2
- CPEB4 | c.*1188_*1191del | 3'UTR (DEL) | VAF 22/43 reads (51%) | catalogued as rs1200749991; called by mutect2, pindel, varscan2
- DLG2 | c.*3510G>A | 3'UTR (SNP) | VAF 23/38 reads (61%) | catalogued as rs990211435; called by muse, mutect2, varscan2
- ELOVL3 | c.-211C>T | 5'UTR (SNP) | VAF 13/163 reads (8%) | catalogued as rs912240012; called by muse, mutect2
- ENSA | c.350+1132G>A | Intron (SNP) | VAF 128/539 reads (24%) | called by muse, mutect2, varscan2
- ENTPD6 | c.1244-13G>A | Intron (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- EPB41L3 | chr18:5630451 ins A | 5'Flank (INS) | VAF 24/56 reads (43%) | catalogued as rs951108873; called by mutect2, varscan2
- ESS2 | c.*3646C>T | 3'UTR (SNP) | VAF 109/220 reads (50%) | catalogued as rs912613177; called by muse, mutect2, varscan2
- FBXO28 | c.*3077G>C | 3'UTR (SNP) | VAF 18/135 reads (13%) | called by muse, mutect2, varscan2
- FBXO30 | c.*1432G>A | 3'UTR (SNP) | VAF 18/47 reads (38%) | called by muse, mutect2, varscan2
- FBXO5 | c.*220A>T | 3'UTR (SNP) | VAF 15/25 reads (60%) | called by muse, mutect2, varscan2
- FEM1B | c.*2468T>C | 3'UTR (SNP) | VAF 38/90 reads (42%) | called by muse, mutect2, varscan2
- FER | c.1924+4621C>A | Intron (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- FMN1 | c.2161+1612C>T | Intron (SNP) | VAF 57/123 reads (46%) | called by muse, mutect2, varscan2
- G3BP1 | c.96-83A>T | Intron (SNP) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- GABRG1 | c.*129A>G | 3'UTR (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- GTPBP10 | c.*5433T>A | 3'UTR (SNP) | VAF 9/93 reads (10%) | called by muse, mutect2
- GTPBP4 | c.460+55C>T | Intron (SNP) | VAF 43/80 reads (54%) | catalogued as rs1321698993; called by muse, mutect2, varscan2
- HBS1L | c.430+2963C>T | Intron (SNP) | VAF 110/261 reads (42%) | called by muse, mutect2, varscan2
- HES3 | c.-3C>T | 5'UTR (SNP) | VAF 16/87 reads (18%) | catalogued as rs1194304270; called by muse, mutect2, varscan2
- ICE2 | c.1125+713G>A | Intron (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- IL6ST | c.*4440dup | 3'UTR (INS) | VAF 14/30 reads (47%) | called by mutect2, varscan2
- ITIH6 | c.*612C>T | 3'UTR (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- JMJD1C | chr10:63466047 A>T | 5'Flank (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2
- KBTBD11 | c.*2359T>C | 3'UTR (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- KLHL14 | c.*29C>G | 3'UTR (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- KTN1 | c.4069+1068C>T | Intron (SNP) | VAF 83/166 reads (50%) | called by muse, mutect2, varscan2
- LCA5 | c.*47T>A | 3'UTR (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- LONRF2 | c.*9544G>A | 3'UTR (SNP) | VAF 71/163 reads (44%) | called by muse, mutect2, varscan2
- LRRC27 | chr10:132376565 G>A | 3'Flank (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- LRRD1 | chr7:92142357 G>A | 3'Flank (SNP) | VAF 152/332 reads (46%) | called by muse, mutect2
- LRRFIP1 | chr2:237765414 G>A | 3'Flank (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- MSL3P1 | n.244G>A | RNA (SNP) | VAF 13/110 reads (12%) | called by muse, varscan2
- MYH16 | n.2415A>C | RNA (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- NAA35 | c.877+8349G>A | Intron (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.2201T>G | RNA (SNP) | VAF 94/237 reads (40%) | called by muse, mutect2, varscan2
- NDUFB10 | chr16:1964979 C>T | 3'Flank (SNP) | VAF 8/49 reads (16%) | catalogued as rs895396912; called by muse, mutect2, varscan2
- NEK9 | c.-65G>A | 5'UTR (SNP) | VAF 12/94 reads (13%) | catalogued as rs978600897; called by muse, mutect2, varscan2
- NEXMIF | c.*1866G>A | 3'UTR (SNP) | VAF 46/106 reads (43%) | catalogued as rs1339275314; called by muse, mutect2, varscan2
- NHLRC2 | c.*254C>A | 3'UTR (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
- OAS2 | c.*659A>G | 3'UTR (SNP) | VAF 23/44 reads (52%) | called by muse, mutect2, varscan2
- PACRG | c.613+89954G>A | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- PARP8 | c.*858C>T | 3'UTR (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- PDE11A | c.-236G>A | 5'UTR (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- PDE7B | c.711+112C>A | Intron (SNP) | VAF 62/120 reads (52%) | called by muse, mutect2, varscan2
- PLCXD3 | c.*351C>T | 3'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- PPP1R3A | c.*362G>A | 3'UTR (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- PPP2R5C | c.630-301G>T | Intron (SNP) | VAF 43/109 reads (39%) | called by muse, mutect2, varscan2
- PRDM10 | c.-95G>A | 5'UTR (SNP) | VAF 120/236 reads (51%) | catalogued as rs765938096; called by muse, mutect2, varscan2
- PSD3 | c.2175+2443G>T | Intron (SNP) | VAF 165/367 reads (45%) | called by muse, mutect2, varscan2
- PTCD1 | c.*2855T>G | 3'UTR (SNP) | VAF 33/67 reads (49%) | called by muse, mutect2, varscan2
- RAB7A | c.*314G>C | 3'UTR (SNP) | VAF 35/310 reads (11%) | called by muse, mutect2, varscan2
- RAD1 | chr5:34907978 C>G | 3'Flank (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- RLIM | c.*1834C>A | 3'UTR (SNP) | VAF 44/88 reads (50%) | called by muse, mutect2, varscan2
- RPL41 | chr12:56117949 T>A | 3'Flank (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- SACS | c.*614C>T | 3'UTR (SNP) | VAF 27/43 reads (63%) | called by muse, mutect2, varscan2
- SEPTIN11 | c.1274+577_1274+578insT | Intron (INS) | VAF 30/75 reads (40%) | called by mutect2, varscan2
- SEPTIN6 | c.*206C>T | 3'UTR (SNP) | VAF 28/50 reads (56%) | called by muse, mutect2, varscan2
- SETD4 | c.-37+186C>T | Intron (SNP) | VAF 43/94 reads (46%) | called by muse, mutect2, varscan2
- SFT2D2 | c.*3386T>C | 3'UTR (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- SHMT2 | chr12:57229651 C>T | 5'Flank (SNP) | VAF 66/189 reads (35%) | called by muse, mutect2, varscan2
- SLC39A6 | c.*61G>A | 3'UTR (SNP) | VAF 14/30 reads (47%) | called by muse, varscan2
- SLITRK4 | c.*248T>G | 3'UTR (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- SOS1 | c.*3630T>A | 3'UTR (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- SPECC1 | c.*50T>C | 3'UTR (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- SPECC1 | chr17:20314912 T>C | 3'Flank (SNP) | VAF 96/200 reads (48%) | called by muse, mutect2, varscan2
- SPECC1 | chr17:20315406 T>C | 3'Flank (SNP) | VAF 30/73 reads (41%) | called by muse, mutect2, varscan2
- SUGCT | c.*215dup | 3'UTR (INS) | VAF 10/24 reads (42%) | catalogued as rs1339459331; called by mutect2, varscan2
- TBC1D26 | c.546+265A>C | Intron (SNP) | VAF 47/179 reads (26%) | called by muse, mutect2, varscan2
- TMEM167A | c.*2708T>A | 3'UTR (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- TMEM18 | c.*1581C>T | 3'UTR (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- TMEM19 | c.847+326C>G | Intron (SNP) | VAF 9/94 reads (10%) | called by muse, mutect2, varscan2
- TMEM30A | c.*1959G>T | 3'UTR (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- TMEM45A | c.-4+26583A>G | Intron (SNP) | VAF 12/274 reads (4%) | called by muse, mutect2
- TMSB10 | c.*170G>A | 3'UTR (SNP) | VAF 44/181 reads (24%) | called by muse, varscan2
- TNFAIP1 | c.*1446C>G | 3'UTR (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- TNS2 | c.697-11_697-10del | Intron (DEL) | VAF 41/102 reads (40%) | called by pindel, varscan2
- TOMM20 | c.*1864G>A | 3'UTR (SNP) | VAF 46/744 reads (6%) | called by muse, mutect2
- TOX | c.*956G>T | 3'UTR (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- TRIM77BP | n.803C>G | RNA (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- UBE2H | c.*3409G>T | 3'UTR (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- UBE2L3 | c.*687C>T | 3'UTR (SNP) | VAF 13/107 reads (12%) | catalogued as rs949931123; called by muse, mutect2, varscan2
- UBR5 | c.*50A>C | 3'UTR (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- VTI1A | c.*892A>T | 3'UTR (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- WNK3 | c.*1430G>A | 3'UTR (SNP) | VAF 34/75 reads (45%) | called by muse, mutect2, varscan2
- ZDHHC7 | c.*1739C>T | 3'UTR (SNP) | VAF 53/101 reads (52%) | called by muse, mutect2, varscan2
- ZNF331 | c.*519T>C | 3'UTR (SNP) | VAF 44/142 reads (31%) | called by muse, mutect2, varscan2
- ZNF704 | c.*5135T>G | 3'UTR (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- ZNF789 | c.152-1775G>C | Intron (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
